Gene-level copy-number profile of tumor specimen TCGA-24-1549-01A from TCGA case TCGA-24-1549, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 58.7 years (21,432 days).
Specimen TCGA-24-1549-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1b88b21c-f2cc-45aa-b55a-ad0cc299124f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1549-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e34d1f9-3d17-4af5-8f9d-fe9ac396e011

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 55; copy number 2: 14,013; copy number 3: 9,316; copy number 4: 30,965; copy number 5: 1,132; copy number 6: 2,486; copy number 7: 277; copy number 8: 465; copy number 9: 758; copy number 10: 185; copy number 11: 90; copy number 12: 25; copy number 13: 4; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1549-01A-01D-0497-01): tumor purity 0.85, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:25,141,394–25,458,476, 8 genes: AC073581.1, AC041005.1, DOCK5, AC091185.2, MIR6876, GNRH1, AC091185.1, KCTD9.
- chr13:48,232,612–48,303,661, 2 genes: ITM2B, RB1-DT.
- chr13:48,316,863–48,444,704, 5 genes (within-gene range 0–1): PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr17:31,094,927–31,382,116, 1 gene (within-gene range 0–2): NF1.
- chr17:31,272,013–31,346,190, 5 genes: OMG, EVI2B, AC134669.1, EVI2A, AK4P1.
- chr17:47,323,290–47,492,492, 3 genes (within-gene range 0–2): EFCAB13, AC040934.1, MRPL45P2.
- chr20:46,997,596–46,998,488, 1 gene: GAPDHP54.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,063 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:31,657,890–32,370,321, 15 genes, copy number 9–12 (within-gene range 4–12): OSBPL10, OSBPL10-AS1, ZNF587P1, ZNF860, RPL21P40, AC094019.1, Y_RNA, NIFKP7, GPD1L, AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15.
- chr3:168,902,194–169,038,416, 4 genes, copy number 13 (within-gene range 7–13): LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:169,613,510–175,810,548, 93 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr3:175,938,929–198,222,513, 486 genes, copy number 9–12 (broad region; genes not listed).
- chr4:119,006,032–119,187,789, 2 genes, copy number 12–14 (within-gene range 4–14): AC096745.1, MYOZ2.
- chr5:58,198–4,147,429, 95 genes, copy number 9 (broad region; genes not listed).
- chr10:93,284,004–93,604,480, 5 genes, copy number 12 (within-gene range 7–12): RPL17P34, MYOF, CEP55, RNA5SP323, FFAR4.
- chr12:26,120,030–26,125,037, 1 gene, copy number 9: BHLHE41.
- chr12:26,125,155–26,167,741, 2 genes, copy number 9: AC022509.3, AC022509.5.
- chr19:8,413,270–10,260,055, 91 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr19:10,259,109–10,260,045, 1 gene, copy number 10: AC011511.3.
- chr19:11,131,520–15,662,825, 267 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr20:15,552,157–15,552,885, 1 gene, copy number 9: AL121584.1.

Autosomal genes at a single copy (total copy number 1): 52. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
